Somatic mutation profile of tumor specimen TARGET-10-PANWDS-09A (aliquot TARGET-10-PANWDS-09A-01D) from TARGET case TARGET-10-PANWDS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,169 days).
Specimen TARGET-10-PANWDS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 509527a8-e13e-4621-bddc-4c27fc6989c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWDS-10A (Blood Derived Normal), aliquot TARGET-10-PANWDS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8525e51-b6de-40df-b771-a9c377beec55

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.4123G>A p.V1375M | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs777421980, COSV53152730; called by muse, mutect2, varscan2
- CDH6 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 60/281 reads (21%) | catalogued as rs771395680, COSV54063694; called by muse, mutect2, varscan2
- DNHD1 | c.7535G>A p.R2512H | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs868212043, COSV54430802; called by muse, mutect2, varscan2
- ACAN | c.196A>T p.T66S | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NCOR1 | c.713_731del p.I238Rfs*41 | Frame Shift Del (DEL) | VAF 54/136 reads (40%) | called by mutect2, pindel, varscan2
- NCOR1 | c.430_435+6delinsC p.X144_splice | Splice Site (DEL) | VAF 12/32 reads (38%) | called by pindel, varscan2*
- OR4K13 | c.829A>G p.I277V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TRAJ29 | c.2_31delinsCCCT p.N2Pfs*? | Frame Shift Del (DEL) | VAF 37/118 reads (31%) | called by pindel, varscan2*
- IGLV4-69 | c.359del p.*120= | Silent (DEL) | VAF 23/73 reads (32%) | called by pindel*, varscan2
- KIF17 | c.2319C>T p.Y773= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as rs373972661; called by muse, mutect2, varscan2
- PAPPA2 | c.531C>T p.F177= | Silent (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
